Somatic mutation profile of tumor specimen PCProject_0130_T1_WES (aliquot PCProject_0130_T1_WES_1) from CMI case PCProject_0130, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.9 years (21,888 days).
Specimen PCProject_0130_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9632aa57-f8ee-4990-9893-2d011e0f9a8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0130_SALIVA (Saliva), aliquot PCProject_0130_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45c49fe1-91c3-4619-967b-5b3038c663a7

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 7, Intron 3, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C10orf71 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs994013054; called by muse, mutect2, varscan2
- COL1A1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.098); catalogued as COSV99868552; called by muse, mutect2
- GRIP2 | c.736G>A p.V246I (on ENST00000619221; = p.V149I on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs1225980454, COSV56122570; called by muse, mutect2, varscan2
- KCNJ15 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as rs534907364, COSV60811503; called by muse, mutect2, varscan2
- MEF2C | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV60924947; called by muse, mutect2
- OR4C13 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as COSV73648697, COSV73648758; called by muse, mutect2
- CASZ1 | c.1806_1807insGTAC p.Y603Vfs*25 | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, pindel
- CDH17 | c.2295C>A p.C765* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- COG5 | c.2182_2184del p.I728del (on ENST00000347053 / NM_001379512.1; = p.I749del on NM_006348.5 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 45/275 reads (16%) | called by pindel, varscan2
- EDC4 | c.3769G>T p.A1257S | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); called by mutect2, varscan2
- EEF1AKNMT | c.1982C>A p.A661D (on ENST00000361735 / NM_015935.5; = p.A575D on NM_014955.3) | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- FSTL1 | c.713A>G p.E238G | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KLK2 | c.273_274insCA p.V92Qfs*13 | Frame Shift Ins (INS) | VAF 45/319 reads (14%) | called by mutect2, pindel*, varscan2*
- MAMLD1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CDON | c.1074T>C p.H358= | Silent (SNP) | VAF 34/213 reads (16%) | called by muse, mutect2, varscan2
- KAT14 | c.1500G>A p.A500= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as rs1422745802, COSV66606719; called by muse, mutect2
- MUC17 | c.12333C>T p.T4111= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs375163227; called by muse, mutect2, varscan2
- MUC6 | c.75C>T p.T25= | Silent (SNP) | VAF 3/19 reads (16%) | called by mutect2, varscan2
- OXR1 | c.6T>C p.S2= | Silent (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- TAX1BP3 | c.171C>T p.V57= | Silent (SNP) | VAF 12/129 reads (9%) | called by muse, mutect2
- TEX2 | c.2322C>G p.L774= (on ENST00000583097 / NM_001288733.2; = p.L781= on NM_018469.5) | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as rs143638344; called by muse, mutect2, varscan2
- NRG1 | c.502+31210C>T | Intron (SNP) | VAF 4/33 reads (12%) | catalogued as rs771642512, COSV55154917; called by mutect2, varscan2
- PABPC1P2 | n.1166C>T | RNA (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- PAPOLA | c.2005-9T>A | Intron (SNP) | VAF 12/96 reads (13%) | catalogued as rs201275170, COSV53478542, COSV53478897; called by muse, mutect2, varscan2
- TASP1 | c.282+8602G>A | Intron (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
